Somatic mutation profile of tumor specimen HCM-BROD-0009-C25-06A (aliquot HCM-BROD-0009-C25-06A-01D-A78W-36) from HCMI case HCM-BROD-0009-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 49.4 years (18,041 days).
Specimen HCM-BROD-0009-C25-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90b08d20-5b21-43a7-8525-255d75b17751.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0009-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0009-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6a562b7-6fbf-4ce6-9bed-47cea14b9d26

The open-access MAF lists 43 somatic variants for this specimen: 24 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 16, Frame Shift Ins 2, Intron 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 223/517 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 79/579 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADCY6 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs988684162; called by muse, mutect2, varscan2
- ATP10D | c.3670G>A p.D1224N | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV56711130; called by muse, mutect2, varscan2
- DGKG | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs375556558; called by muse, mutect2, varscan2
- FAM124B | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1280865122, COSV54739336; called by muse, mutect2, varscan2
- GPR158 | c.3343G>T p.G1115W | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV66265522; called by muse, mutect2, varscan2
- HSPB1 | c.126G>T p.W42C | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs896004429; called by muse, mutect2, varscan2
- MAP10 | c.2228A>C p.K743T | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); catalogued as COSV69363590; called by muse, mutect2, varscan2
- OR11H1 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 62/700 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs537405197, COSV53271623; called by muse, mutect2
- RAB29 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1313676783; called by mutect2, varscan2
- SCN4A | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1227159244, COSV71125975; called by muse, mutect2, varscan2
- SCN9A | c.5837C>A p.T1946K (on ENST00000303354; = p.T1935K on NM_002977.3) | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57604382; called by muse, mutect2
- SRRM4 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV57428953; called by muse, mutect2, varscan2
- ZNF462 | c.5617G>T p.D1873Y | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52952959; called by muse, mutect2, varscan2
- ERVV-1 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 50/388 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- GRIA2 | c.608dup p.E204Gfs*9 | Frame Shift Ins (INS) | VAF 21/131 reads (16%) | called by mutect2, pindel, varscan2
- KIF5B | c.2019G>T p.Q673H | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2
- LTBP2 | c.3477G>T p.Q1159H | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NRDE2 | c.1918T>C p.F640L | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OR11H1 | c.690G>T p.L230F | Missense Mutation (SNP) | VAF 62/704 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.492); called by muse, mutect2
- POLR2H | c.381_382dup p.D128Gfs*18 | Frame Shift Ins (INS) | VAF 17/159 reads (11%) | called by mutect2, pindel
- TDRD15 | c.3492A>T p.R1164S | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF566 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.221); called by muse, mutect2
- ABCG5 | c.1329C>T p.P443= | Silent (SNP) | VAF 48/444 reads (11%) | catalogued as rs201620171; called by muse, mutect2, varscan2
- BRCA2 | c.2043A>G p.V681= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs747363339; ClinVar: likely benign; called by muse, mutect2
- GGT5 | c.1596C>T p.Y532= | Silent (SNP) | VAF 26/155 reads (17%) | catalogued as rs745874439, COSV54071049; called by muse, mutect2, varscan2
- INTS2 | c.1080G>C p.V360= | Silent (SNP) | VAF 16/372 reads (4%) | called by muse, mutect2
- KDM3B | c.2121C>T p.G707= | Silent (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- MACF1 | c.21510A>T p.G7170= (on ENST00000372915; = p.G5215= on NM_012090.5) | Silent (SNP) | VAF 30/207 reads (14%) | called by muse, mutect2, varscan2
- NR1H4 | c.1065G>A p.P355= (on ENST00000551379 / NM_001206993.2; = p.P341= on NM_005123.4) | Silent (SNP) | VAF 42/359 reads (12%) | catalogued as rs569479207, COSV51857715; called by muse, mutect2, varscan2
- NYAP2 | c.1278C>T p.P426= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1305682005; called by muse, mutect2, varscan2
- OR5AN1 | c.594C>T p.V198= | Silent (SNP) | VAF 19/181 reads (10%) | catalogued as COSV58321558, COSV58321835; called by muse, mutect2, varscan2
- RPL3 | c.477C>T p.V159= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as rs766432864; called by muse, mutect2, varscan2
- SIGLEC11 | c.192C>T p.D64= | Silent (SNP) | VAF 51/332 reads (15%) | catalogued as rs762185501; called by muse, mutect2, varscan2
- SLCO1C1 | c.1092T>C p.V364= | Silent (SNP) | VAF 48/288 reads (17%) | called by muse, mutect2, varscan2
- SMARCA4 | c.4254C>T p.D1418= | Silent (SNP) | VAF 34/297 reads (11%) | catalogued as rs370380553; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZFHX4 | c.4212G>A p.L1404= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV51500925; called by muse, mutect2
- ZNF598 | c.1062C>T p.A354= | Silent (SNP) | VAF 20/172 reads (12%) | catalogued as rs752141278; called by muse, mutect2
- ZSCAN5A | c.219G>A p.L73= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as COSV54227655; called by muse, mutect2, varscan2
- AC018563.1 | n.682G>A | RNA (SNP) | VAF 12/174 reads (7%) | catalogued as rs1401741243; called by muse, mutect2
- FAM153CP | chr5:178056087 C>T | 3'Flank (SNP) | VAF 30/396 reads (8%) | catalogued as rs762773407; called by muse, mutect2
- PNKD | c.237-16524G>A | Intron (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
